Somatic mutation profile of tumor specimen TCGA-13-0903-01A (aliquot TCGA-13-0903-01A-01W-0420-08) from TCGA case TCGA-13-0903, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 43.0 years (15,705 days).
Specimen TCGA-13-0903-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e29d68cb-7e2f-4de2-9a58-20fc899115ef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-0903-10A (Blood Derived Normal), aliquot TCGA-13-0903-10A-01W-0420-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2c1be523-3392-4915-9968-388628dca563

The open-access MAF lists 145 somatic variants for this specimen: 106 protein-altering or splice-affecting, 32 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 96, Silent 32, Nonsense Mutation 4, Splice Site 3, RNA 3, Intron 2, Frame Shift Ins 2, In Frame Del 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.614A>G p.Y205C | Missense Mutation (SNP) | VAF 445/542 reads (82%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057520007, COSV52665440, COSV52677268, COSV52688506; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.440G>A p.G147D | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.694); catalogued as COSV56473168; called by muse, mutect2
- ABI3BP | c.588C>G p.D196E | Missense Mutation (SNP) | VAF 15/179 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52535263, COSV52546050; called by muse, mutect2
- ACACB | c.3759G>T p.M1253I | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT tolerated (0.21); PolyPhen benign (0.014); catalogued as COSV100623319, COSV58142350; called by muse, mutect2, varscan2
- ADGRG7 | c.581G>A p.R194K | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV56295442, COSV56296535; called by muse, mutect2
- ANK3 | c.12118G>A p.E4040K | Missense Mutation (SNP) | VAF 18/199 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.566); catalogued as rs201115226, COSV55050851; called by muse, mutect2
- AQP4 | c.573A>T p.L191F | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV101270549; called by muse, mutect2
- ARHGAP36 | c.1414C>A p.L472I | Missense Mutation (SNP) | VAF 218/450 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.048); catalogued as COSV52270236; called by muse, mutect2, varscan2
- ARID1B | c.3570G>A p.M1190I | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.366); catalogued as COSV99270993; called by muse, mutect2
- AZIN2 | c.1325G>A p.W442* | Nonsense Mutation (SNP) | VAF 12/290 reads (4%) | catalogued as COSV99613646; called by muse, mutect2
- C3orf52 | c.403G>A p.D135N | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as COSV99332608; called by muse, varscan2
- CCDC191 | c.737A>T p.E246V | Missense Mutation (SNP) | VAF 144/512 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.44); catalogued as COSV55674975; called by muse, varscan2
- CCDC28B | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 14/245 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.35); catalogued as COSV99356744; called by muse, mutect2
- CCDC88B | c.1489G>C p.V497L | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs778114059, COSV57267502; called by muse, mutect2, varscan2
- CDC42BPB | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 358/726 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.666); catalogued as rs781414650, COSV100775558; called by muse, mutect2, varscan2
- CDHR5 | c.1641dup p.G548Rfs*161 (on ENST00000358353 / NM_001171968.2; = p.G554Rfs*161 on NM_021924.5) | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | catalogued as rs775160782; called by pindel, varscan2
- CEP131 | c.979G>T p.A327S | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.521); catalogued as COSV53955244; called by muse, mutect2, varscan2
- CLCNKB | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.574); catalogued as rs539214175, COSV65161271; called by muse, varscan2
- COL11A2 | c.1826G>A p.R609Q (on ENST00000341947 / NM_080680.3; = p.R502Q on NM_080679.2) | Missense Mutation (SNP) | VAF 30/487 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs760066546, COSV100554371; called by muse, mutect2
- COL23A1 | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0.246); catalogued as COSV101179477; called by muse, mutect2
- COL4A4 | c.2822C>T p.S941F | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV100307426; called by muse, mutect2
- CPVL | c.864+2T>G p.X288_splice | Splice Site (SNP) | VAF 131/229 reads (57%) | catalogued as COSV55306292; called by muse, mutect2, varscan2
- DAB2 | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 18/534 reads (3%) | SIFT tolerated (0.05); PolyPhen benign (0.053); catalogued as COSV57913731; called by muse, mutect2
- DNAH9 | c.11602G>T p.D3868Y | Missense Mutation (SNP) | VAF 98/160 reads (61%) | SIFT tolerated (0.08); PolyPhen benign (0.035); catalogued as rs1567890901, COSV52332125, COSV52345762; called by muse, mutect2, varscan2
- DOCK6 | c.5894G>A p.R1965Q | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.478); catalogued as rs766894749, COSV53913545, COSV53919723; called by muse, mutect2, varscan2
- DUSP4 | c.854C>T p.S285L | Missense Mutation (SNP) | VAF 11/151 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53544999; called by muse, mutect2
- EPHB3 | c.1372A>G p.T458A | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.356); catalogued as COSV100383212; called by mutect2, varscan2
- FASN | c.5543A>G p.H1848R | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100148142; called by muse, mutect2
- FDXACB1 | c.1131T>A p.F377L | Missense Mutation (SNP) | VAF 109/284 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52790065; called by muse, mutect2, varscan2
- FKBP15 | c.3391T>A p.S1131T | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV53037986; called by mutect2, varscan2
- FNBP1 | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 13/260 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV100852759; called by muse, mutect2
- FOS | c.733A>C p.N245H | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.201); catalogued as COSV57840117; called by muse, mutect2
- FOXA2 | c.519G>T p.Q173H (on ENST00000377115 / NM_153675.3; = p.Q179H on NM_021784.5) | Missense Mutation (SNP) | VAF 104/252 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.194); catalogued as COSV65796787; called by muse, mutect2, varscan2
- GOLGB1 | c.8365G>A p.A2789T | Missense Mutation (SNP) | VAF 81/203 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs770543826, COSV61463196; called by muse, mutect2, varscan2
- GTF3C1 | c.2669C>T p.P890L | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100649894; called by muse, mutect2
- GTF3C1 | c.2198G>A p.G733E | Missense Mutation (SNP) | VAF 99/195 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62243652; called by muse, mutect2, varscan2
- HDAC3 | c.420+1G>T p.X140_splice | Splice Site (SNP) | VAF 107/314 reads (34%) | catalogued as COSV59497065; called by muse, mutect2, varscan2
- HJURP | c.1360C>T p.R454C | Missense Mutation (SNP) | VAF 18/209 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs770064280, COSV64979464; called by muse, mutect2
- IQGAP1 | c.2861A>G p.Q954R | Missense Mutation (SNP) | VAF 413/464 reads (89%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as COSV51589257; called by muse, mutect2, varscan2
- ITGAL | c.172G>A p.V58M | Missense Mutation (SNP) | VAF 210/475 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769585343, COSV63323605; called by muse, mutect2, varscan2
- ITGB2 | c.55T>A p.C19S | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV100186044; called by muse, mutect2, varscan2
- KCMF1 | c.506C>T p.S169L | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as COSV69054494; called by muse, mutect2, varscan2
- KIF27 | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 21/200 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs151248208, COSV99927189; called by muse, mutect2, varscan2
- LARGE1 | c.1410C>G p.D470E | Missense Mutation (SNP) | VAF 73/99 reads (74%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as COSV61668198; called by muse, mutect2, varscan2
- LIPI | c.1003A>T p.R335W | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV60714727; called by muse, mutect2, varscan2
- LRRK1 | c.1417G>A p.D473N | Missense Mutation (SNP) | VAF 34/800 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.316); catalogued as COSV99442050; called by muse, mutect2
- LYST | c.2509C>T p.P837S | Missense Mutation (SNP) | VAF 180/522 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as COSV67710715; called by muse, mutect2, varscan2
- MATN2 | c.2282G>A p.R761K | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.996); catalogued as COSV99646834; called by muse, mutect2, varscan2
- MCM3 | c.1904C>T p.A635V (on ENST00000229854 / NM_001366374.2; = p.A625V on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/412 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV100008964; called by muse, mutect2
- MED1 | c.641G>A p.R214K | Missense Mutation (SNP) | VAF 28/230 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs1280957223, COSV100328052; called by muse, varscan2
- MERTK | c.999G>A p.M333I | Missense Mutation (SNP) | VAF 144/1078 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV54931674; called by muse, mutect2, varscan2
- MFSD2B | c.277G>T p.A93S | Missense Mutation (SNP) | VAF 85/168 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.405); catalogued as COSV57855771; called by muse, mutect2, varscan2
- MIER2 | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 56/122 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as rs370003436, COSV53395754; called by muse, varscan2
- MMP3 | c.190dup p.I64Nfs*33 | Frame Shift Ins (INS) | VAF 94/242 reads (39%) | catalogued as rs782038929; called by mutect2, varscan2
- MMP8 | c.872T>C p.L291P | Missense Mutation (SNP) | VAF 177/394 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52633848; called by muse, varscan2
- MOCS3 | c.133C>A p.P45T | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.58); PolyPhen benign (0.036); catalogued as COSV54867409, COSV54868232; called by muse, mutect2, varscan2
- MSH4 | c.2224G>T p.E742* | Nonsense Mutation (SNP) | VAF 14/62 reads (23%) | catalogued as COSV54208648; called by muse, mutect2, varscan2
- MYH6 | c.2021G>A p.C674Y | Missense Mutation (SNP) | VAF 101/647 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100676852; called by muse, mutect2, varscan2
- MYO5A | c.326C>G p.A109G | Missense Mutation (SNP) | VAF 57/128 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1487252374, COSV62563079; called by muse, mutect2, varscan2
- MYO9B | c.3199G>A p.A1067T | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV101261774; called by muse, mutect2
- NOTCH4 | c.756G>A p.M252I | Missense Mutation (SNP) | VAF 115/433 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV66681069, COSV66683311; called by muse, mutect2, varscan2
- OPRM1 | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 94/660 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.579); catalogued as COSV100000288; called by muse, mutect2, varscan2
- OPRM1 | c.803C>T p.S268F | Missense Mutation (SNP) | VAF 108/605 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100002048; called by muse, mutect2, varscan2
- OR2T1 | c.322G>A p.G108R | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100822341; called by muse, mutect2
- OR2T34 | c.178C>A p.L60I | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60901372; called by muse, mutect2, varscan2
- PAPPA2 | c.3058G>T p.V1020L | Missense Mutation (SNP) | VAF 253/556 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as rs201517784, COSV62806749; called by muse, mutect2, varscan2
- PARP16 | c.457G>A p.G153S | Missense Mutation (SNP) | VAF 10/230 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99975604; called by muse, mutect2
- PCDHA3 | c.636A>G p.I212M | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.616); catalogued as COSV65369886; called by muse, mutect2, varscan2
- PGAP1 | c.944A>G p.K315R | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV61328409; called by muse, mutect2, varscan2
- PLEKHG4B | c.1061C>T p.A354V (on ENST00000283426; = p.A710V on NM_052909.5) | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.039); catalogued as COSV99360816; called by muse, mutect2
- PLPPR1 | c.842G>A p.G281E | Missense Mutation (SNP) | VAF 37/862 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1324816491, COSV100883426; called by muse, mutect2
- POF1B | c.167G>A p.S56N | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV99427166; called by muse, mutect2
- POTEF | c.1927G>C p.D643H | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.354); catalogued as COSV100665169; called by muse, mutect2, varscan2
- PSMB5 | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV100557387; called by muse, varscan2
- PSMB5 | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.102); catalogued as rs779907342, COSV100557389; called by muse, varscan2
- PZP | c.2360C>T p.S787F | Missense Mutation (SNP) | VAF 14/291 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54370402, COSV99738880; called by muse, mutect2
- RAVER1 | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV99349215; called by muse, varscan2
- RC3H2 | c.1765T>C p.Y589H | Missense Mutation (SNP) | VAF 501/843 reads (59%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.969); catalogued as COSV61801929; called by muse, mutect2, varscan2
- ROR1 | c.547G>A p.G183S | Missense Mutation (SNP) | VAF 54/633 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.644); catalogued as COSV64291307; called by muse, mutect2
- RRP12 | c.3160G>A p.E1054K | Missense Mutation (SNP) | VAF 45/290 reads (16%) | SIFT tolerated (0.77); PolyPhen benign (0.086); catalogued as COSV100213360; called by muse, mutect2, varscan2
- RYR2 | c.11687A>T p.D3896V | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV63703862; called by muse, mutect2, varscan2
- SDCBP2 | c.28G>C p.D10H | Missense Mutation (SNP) | VAF 202/541 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60590399; called by muse, mutect2, varscan2
- SEC23B | c.346A>C p.T116P | Missense Mutation (SNP) | VAF 102/193 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV52722683; called by muse, mutect2, varscan2
- SLC23A2 | c.233G>C p.S78T | Missense Mutation (SNP) | VAF 43/173 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV57777734; called by muse, mutect2, varscan2
- SLC35F4 | c.152C>A p.S51* | Nonsense Mutation (SNP) | VAF 45/105 reads (43%) | catalogued as rs766937984, COSV60266301; called by muse, mutect2, varscan2
- SLCO1C1 | c.1490C>A p.T497K | Missense Mutation (SNP) | VAF 80/193 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99859653; called by muse, mutect2, varscan2
- STK11IP | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 76/116 reads (66%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV55247570, COSV55253662; called by muse, mutect2, varscan2
- SZT2 | c.5212C>T p.R1738C (on ENST00000634258 / NM_001365999.1; = p.R1681C on NM_015284.4) | Missense Mutation (SNP) | VAF 352/866 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs1443080592, COSV100987551; called by muse, mutect2, varscan2
- TBK1 | c.1575A>T p.R525S | Missense Mutation (SNP) | VAF 218/288 reads (76%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV59157569; called by muse, mutect2, varscan2
- TTLL5 | c.3118C>T p.Q1040* | Nonsense Mutation (SNP) | VAF 52/185 reads (28%) | catalogued as COSV100091178; called by muse, mutect2, varscan2
- WDR82 | c.113C>T p.S38L | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.228); catalogued as COSV56601441, COSV99627124; called by muse, mutect2
- XDH | c.3098C>G p.T1033S | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.092); catalogued as rs757665079, COSV65150479; called by muse, mutect2, varscan2
- ZNF12 | c.1250G>C p.C417S (on ENST00000405858 / NM_016265.4; = p.C379S on NM_006956.3) | Missense Mutation (SNP) | VAF 18/321 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV100703815; called by muse, mutect2
- ZNF12 | c.1249T>A p.C417S (on ENST00000405858 / NM_016265.4; = p.C379S on NM_006956.3) | Missense Mutation (SNP) | VAF 16/320 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV100703816; called by muse, mutect2
- ZNF592 | c.3184G>C p.E1062Q | Missense Mutation (SNP) | VAF 59/128 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as COSV55438712; called by muse, mutect2, varscan2
- ZP1 | c.539C>T p.P180L | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV99612716; called by muse, mutect2, varscan2
- ARHGEF37 | c.1547A>C p.N516T | Missense Mutation (SNP) | VAF 174/280 reads (62%) | SIFT tolerated (0.16); PolyPhen benign (0.19); called by mutect2, varscan2
- ATG2B | c.913_924+19del p.X305_splice | Splice Site (DEL) | VAF 42/173 reads (24%) | called by mutect2, pindel
- BTN3A2 | c.605A>C p.Y202S | Missense Mutation (SNP) | VAF 204/1058 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by mutect2, varscan2
- FASTKD5 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 45/254 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- GJA8 | c.79_108del p.T27_I36del | In Frame Del (DEL) | VAF 102/706 reads (14%) | called by mutect2*, pindel
- ICE2 | c.2843C>T p.T948I | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.013); called by muse, varscan2
- PCK1 | c.1771G>A p.D591N | Missense Mutation (SNP) | VAF 83/268 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLX4 | c.3173C>T p.T1058I | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.013); called by mutect2, varscan2
- SVEP1 | c.7426A>T p.T2476S | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.01); called by muse, varscan2
- TRAV4 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 9/252 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- ABCC1 | c.789G>A p.K263= | Silent (SNP) | VAF 52/1092 reads (5%) | called by muse, mutect2
- ABCC6 | c.3042C>G p.A1014= | Silent (SNP) | VAF 24/103 reads (23%) | catalogued as COSV99229301; called by muse, mutect2, varscan2
- AKNAD1 | c.1239G>A p.K413= | Silent (SNP) | VAF 38/376 reads (10%) | catalogued as COSV100645768; called by muse, varscan2
- ALPL | c.450C>T p.I150= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as rs1383812469, COSV100876933; called by muse, mutect2, varscan2
- ANKRD44 | c.2424G>A p.L808= | Silent (SNP) | VAF 46/142 reads (32%) | catalogued as COSV56561967; called by muse, mutect2, varscan2
- CIBAR2 | c.576C>T p.F192= | Silent (SNP) | VAF 11/209 reads (5%) | catalogued as COSV101608290; called by muse, mutect2
- COL17A1 | c.2445G>A p.S815= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV62225860; called by muse, mutect2, varscan2
- CYP4F3 | c.240G>A p.L80= | Silent (SNP) | VAF 91/233 reads (39%) | catalogued as COSV55412364; called by muse, mutect2, varscan2
- FCRL3 | c.2148A>G p.E716= | Silent (SNP) | VAF 76/199 reads (38%) | catalogued as COSV63843850; called by muse, mutect2, varscan2
- FLAD1 | c.1296G>A p.Q432= | Silent (SNP) | VAF 42/1334 reads (3%) | catalogued as COSV99422854; called by muse, mutect2
- GRK6 | c.328C>T p.L110= | Silent (SNP) | VAF 626/1052 reads (60%) | catalogued as rs762693423, COSV100586985; called by mutect2, varscan2
- IL17RB | c.1209G>C p.V403= | Silent (SNP) | VAF 430/492 reads (87%) | catalogued as COSV99213838; called by mutect2, varscan2
- ITPR3 | c.405G>A p.V135= | Silent (SNP) | VAF 66/1555 reads (4%) | catalogued as COSV100967837; called by muse, mutect2
- LYPD6B | c.99A>C p.S33= (on ENST00000409029 / NM_001317004.1; = p.S57= on NM_177964.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 40/552 reads (7%) | catalogued as COSV99700406; called by muse, mutect2
- MECR | c.876C>T p.P292= | Silent (SNP) | VAF 18/31 reads (58%) | catalogued as rs774083968, COSV55284163, COSV55286889; called by muse, mutect2, varscan2
- MME | c.597C>G p.V199= | Silent (SNP) | VAF 39/102 reads (38%) | catalogued as COSV64709330; called by muse, mutect2, varscan2
- MYO10 | c.4689C>T p.T1563= | Silent (SNP) | VAF 16/118 reads (14%) | catalogued as rs780379182, COSV99945967; called by muse, varscan2
- P4HB | c.492G>A p.V164= | Silent (SNP) | VAF 19/479 reads (4%) | catalogued as COSV100515894; called by muse, mutect2
- RRP8 | c.240A>C p.S80= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as rs767107832; called by mutect2, varscan2
- SATB1 | c.801C>G p.V267= | Silent (SNP) | VAF 25/55 reads (45%) | catalogued as rs764362388, COSV58671722; called by muse, mutect2, varscan2
- SLC6A19 | c.1746G>A p.V582= | Silent (SNP) | VAF 143/607 reads (24%) | catalogued as rs761780267, COSV57253531, COSV99722549; called by muse, mutect2, varscan2
- SLC9A7 | c.1053C>T p.T351= | Silent (SNP) | VAF 13/201 reads (6%) | catalogued as COSV100091742, COSV100092560; called by muse, mutect2
- SLCO1C1 | c.1491A>G p.T497= | Silent (SNP) | VAF 81/191 reads (42%) | catalogued as rs1350700138, COSV56881976; called by muse, mutect2, varscan2
- STING1 | c.1029G>A p.V343= | Silent (SNP) | VAF 78/302 reads (26%) | catalogued as rs1349606923; called by mutect2, varscan2
- STK33 | c.1470G>A p.V490= | Silent (SNP) | VAF 681/1016 reads (67%) | catalogued as rs769366653, COSV59406698; called by muse, mutect2, varscan2
- STRIP1 | c.306G>A p.E102= | Silent (SNP) | VAF 153/547 reads (28%) | catalogued as COSV100873985; called by muse, mutect2, varscan2
- TMEM143 | c.9C>T p.V3= | Silent (SNP) | VAF 20/147 reads (14%) | catalogued as rs201886937, COSV99507452; called by muse, varscan2
- TRBV24-1 | c.312G>A p.Q104= | Silent (SNP) | VAF 21/530 reads (4%) | called by muse, mutect2
- UNC5D | c.948A>G p.E316= | Silent (SNP) | VAF 54/126 reads (43%) | catalogued as COSV54820864; called by muse, mutect2, varscan2
- USHBP1 | c.129C>T p.A43= | Silent (SNP) | VAF 16/93 reads (17%) | called by mutect2, varscan2
- YY1 | c.102G>A p.E34= | Silent (SNP) | VAF 22/22 reads (100%) | catalogued as COSV99216935; called by muse, varscan2
- ZP1 | c.540C>T p.P180= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV53924174, COSV99612720; called by muse, mutect2, varscan2
- ABLIM2 | c.1168+1876_1168+1878del | Intron (DEL) | VAF 50/170 reads (29%) | called by pindel, varscan2
- AGAP7P | n.1525T>C | RNA (SNP) | VAF 26/310 reads (8%) | called by muse, mutect2
- ARNT2 | c.*3523C>T | 3'UTR (SNP) | VAF 50/521 reads (10%) | catalogued as rs764320581, COSV57592247; called by muse, mutect2, varscan2
- BPI | c.-1G>A | 5'UTR (SNP) | VAF 26/486 reads (5%) | catalogued as COSV99480873; called by muse, mutect2
- POLR2F | c.453-15066C>T | Intron (SNP) | VAF 122/509 reads (24%) | called by muse, mutect2, varscan2
- SNORD115-19 | n.82C>T | RNA (SNP) | VAF 16/220 reads (7%) | catalogued as rs188758741; called by muse, mutect2
- SNORD116-2 | n.77C>A | RNA (SNP) | VAF 189/385 reads (49%) | called by muse, mutect2, varscan2
